Somatic mutation profile of tumor specimen TCGA-EM-A22P-01A (aliquot TCGA-EM-A22P-01A-11D-A19J-08) from TCGA case TCGA-EM-A22P, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage IVA; Age at diagnosis: 65.0 years (23,723 days).
Specimen TCGA-EM-A22P-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 04bcbea1-f0ce-4a37-b2e7-a71f0b9248fa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EM-A22P-10A (Blood Derived Normal), aliquot TCGA-EM-A22P-10A-01D-A19M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3f858367-8bb1-41d6-b4d5-1ef4554d554e

The open-access MAF lists 14 somatic variants for this specimen: 10 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 8, Silent 4, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- AQP4 | c.30G>A p.W10* | Nonsense Mutation (SNP) | VAF 37/164 reads (23%) | catalogued as rs774486714, COSV67218589; called by muse, mutect2, varscan2
- ATG2A | c.1127C>T p.A376V | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.055); catalogued as COSV65966594; called by muse, mutect2, varscan2
- C1orf141 | c.64A>G p.R22G | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.173); catalogued as rs1242618465, COSV63992566; called by muse, mutect2, varscan2
- MUC16 | c.1295C>A p.T432N | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV67462719; called by muse, mutect2, varscan2
- PRRG1 | c.335G>A p.R112K | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV66157460; called by muse, mutect2, varscan2
- RALGPS2 | c.715A>G p.I239V | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.385); catalogued as COSV61336902; called by muse, mutect2, varscan2
- TBK1 | c.1927G>A p.E643K | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.187); catalogued as COSV59154905; called by muse, mutect2
- USP48 | c.2089-1G>C p.X697_splice | Splice Site (SNP) | VAF 34/119 reads (29%) | catalogued as COSV57609504; called by muse, mutect2, varscan2
- ZNF185 | c.2054A>T p.Y685F | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59275658; called by muse, mutect2
- ABCA4 | c.2805A>G p.V935= | Silent (SNP) | VAF 56/248 reads (23%) | catalogued as COSV64673220; called by muse, mutect2, varscan2
- DDX56 | c.1425G>A p.R475= | Silent (SNP) | VAF 3/44 reads (7%) | catalogued as rs1247153451, COSV99346034; called by muse, mutect2
- H2BC7 | c.165C>T p.I55= | Silent (SNP) | VAF 62/299 reads (21%) | catalogued as COSV61911874; called by muse, mutect2, varscan2
- TIE1 | c.333G>A p.A111= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as rs774340072, COSV65249562; called by muse, mutect2, varscan2
